Somatic mutation profile of tumor specimen TCGA-EA-A5O9-01A (aliquot TCGA-EA-A5O9-01A-11D-A28B-09) from TCGA case TCGA-EA-A5O9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Exocervix; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 39.6 years (14,472 days).
Specimen TCGA-EA-A5O9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffe9126c-739b-4a6a-b0f8-32b195dc046b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A5O9-10A (Blood Derived Normal), aliquot TCGA-EA-A5O9-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3988124-4f05-467e-a791-53f5a6d78589

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 3, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 17/21 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.501); catalogued as COSV55390944; called by muse, mutect2, varscan2
- ADRB2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60005226; called by muse, mutect2, varscan2
- AHCTF1 | c.3283T>C p.S1095P (on ENST00000366508; = p.S1069P on NM_015446.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58246111; called by muse, mutect2, varscan2
- ASH1L | c.3347G>C p.G1116A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64205701; called by muse, mutect2, varscan2
- BRF1 | c.1598_1600del p.K533del | In Frame Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs868673013; called by pindel, varscan2
- CFAP74 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs1323001300, COSV54564829; called by muse, mutect2, varscan2
- CNTLN | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV52067158; called by muse, mutect2
- CPNE4 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV70190261; called by muse, mutect2, varscan2
- CXCR2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs200906463, COSV59279825; called by muse, mutect2, varscan2
- DENND1B | c.2009A>G p.K670R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV54153583; called by muse, mutect2, varscan2
- DMD | c.4292A>C p.N1431T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV63736278; called by muse, mutect2, varscan2
- DNAI3 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs199712026; called by muse, mutect2, varscan2
- DSG3 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV57124291; called by muse, mutect2, varscan2
- ESRP2 | c.1303C>T p.R435W (on ENST00000565858 / NM_001365264.1; = p.R425W on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52172093, COSV99251530; called by muse, mutect2, varscan2
- FTHL17 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs965356836, COSV63266410; called by muse, mutect2, varscan2
- GAS6 | c.803T>A p.L268H | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV59847472; called by muse, mutect2, varscan2
- GOLGA4 | c.5678G>A p.R1893K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62709340; called by muse, mutect2, varscan2
- HTR2C | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.369); catalogued as rs868980082, COSV52202281; called by muse, mutect2, varscan2
- IPO13 | c.1760G>T p.C587F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV64893829; called by muse, mutect2, varscan2
- KCND3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as rs760055752, COSV56175627; called by muse, mutect2, varscan2
- KDM2A | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV58188665; called by muse, mutect2, varscan2
- KLHL22 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1472017813, COSV56731161; called by muse, mutect2, varscan2
- MAP3K15 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58826259; called by muse, mutect2, varscan2
- MED14 | c.869A>T p.Q290L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61355934; called by muse, mutect2, varscan2
- NBPF3 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59056863; called by muse, mutect2
- NT5C1A | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.942); catalogued as rs1289830312, COSV52493247; called by muse, mutect2, varscan2
- PKD2L1 | c.314T>C p.L105S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV58394683; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs782076287; called by mutect2, varscan2
- POLQ | c.3866C>A p.S1289Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV99951747; called by muse, mutect2
- RHOD | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1192716657, COSV58211130; called by muse, mutect2, varscan2
- SH2D7 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs747211880, COSV60926036; called by muse, mutect2, varscan2
- SLC39A5 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282039930, COSV57190697; called by muse, mutect2, varscan2
- SLC6A3 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs75916702, COSV54361807; called by muse, mutect2, varscan2
- TBC1D5 | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53749881; called by muse, mutect2, varscan2
- TMEM129 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1323489235, COSV57558663; called by muse, mutect2, varscan2
- TOGARAM2 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs200703318, COSV101090922; called by muse, mutect2, varscan2
- TRPV2 | c.1770C>A p.Y590* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58427368; called by muse, mutect2
- TRRAP | c.7066G>A p.E2356K (on ENST00000359863 / NM_001244580.1; = p.E2338K on NM_003496.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV62839467; called by muse, mutect2, varscan2
- TSSK1B | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs770706524, COSV66814886; called by muse, mutect2, varscan2
- ZNF214 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99547233, COSV99547619; called by muse, mutect2, varscan2
- ZNF419 | c.1309A>T p.S437C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV55657680; called by muse, mutect2, varscan2
- ZNF786 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs749658480, COSV60275068; called by muse, mutect2, varscan2
- COQ3 | c.251dup p.Y85Vfs*12 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- AFF2 | c.3384T>A p.S1128= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53977723, COSV53992700; called by muse, mutect2, varscan2
- IRF8 | c.957C>A p.V319= | Silent (SNP) | VAF 58/66 reads (88%) | catalogued as COSV51896763; called by muse, mutect2, varscan2
- KAAG1 | c.219C>T p.N73= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1388683622, COSV51239529; called by muse, mutect2, varscan2
- KCNQ3 | c.1491G>A p.A497= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs760918194, COSV66465725; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB16 | c.657T>C p.R219= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV67873563; called by muse, mutect2, varscan2
- MTOR | c.6840G>A p.L2280= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV63868641; called by muse, mutect2, varscan2
- PLD1 | c.1464C>T p.D488= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs770891509, COSV60565638; called by muse, mutect2, varscan2
- PLEKHO1 | c.366G>A p.S122= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1553820539, COSV50309803; called by mutect2, varscan2
- PRKN | c.270C>T p.N90= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs767425151, COSV58203773; called by muse, mutect2, varscan2
- RPS6KA2 | c.1068G>A p.T356= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs376127612; called by muse, mutect2, varscan2
- SEMA3A | c.864A>G p.K288= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1049702716, COSV54862407; called by muse, mutect2, varscan2
- SLCO1B1 | c.1152T>G p.P384= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV57007441; called by muse, mutect2, varscan2
- SND1 | c.2298C>T p.Y766= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs747235161, COSV61235518; called by muse, mutect2
- ZNF48 | c.1050C>G p.L350= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV60782438; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764716 C>T | 3'Flank (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
